TARGET case TARGET-10-PANURW — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d38d8d63-9cff-5c88-9407-fc520be325bc

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 15 years; Vital status: Dead; Days to death: 355 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.3 years (5,598 days); Year of diagnosis: 2005; Days to last follow up: 355 days.
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 28 days; Days to first event: 28 days; First event: Induction Failure.
- Days to follow up: 355 days; Year of follow up: 2006.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Positive.
- Day 0: Leukocytes 4.8 ×10³/µL.
- Day 8: Bone Marrow blast count 32%.
- Day 15: Bone Marrow blast count 3%.
- Day 29: Bone Marrow blast count 70%; Minimal Residual Disease (Flow Cytometry) 26.4%.

Biospecimens (2 samples)
- Sample TARGET-10-PANURW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PANURW-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 355
- WBC at Diagnosis: 4.8
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 29: 26.4
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- BCR ABL1 Status: Positive
- BMA Blasts Day 8: 32
- BMA Blasts Day 15: 3
- BMA Blasts Day 29: 70
- Karyotype: 46,X,inv(Y)(p11.2q11.2)c[20]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: BCR-ABL1
